FM case AD3650 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Vulva.
https://portal.gdc.cancer.gov/cases/b8c24c69-9fcc-414d-983d-97a4852c85a9

Female, 80.9 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the vulva; metastasis biopsied or resected from the connective, subcutaneous and other soft tissues. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Metastatic.
